Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5KY, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5KY-01A (Primary Tumor).

ICD-O-3
Carcinoma, adrenal cortical
8370/3
Site: Adrenal Gland, cortex
C74.0
JW 2/6/13

Procedure: L adrenalectomy, nephrectomy,

Gross description: 10 x 6.5 x 6.5cm

Diagnosis: adrenocortical carcinoma, pT3 pN1 pM1(LYM) L1 V1 Pn0 R0, 52/52 LN positive

Reference Pathology:

Diagnosis: adrenocortical carcinoma, KI67 10-20%

Weiss score: 4

Hough score: 0.97

Van Slooten score: 12.3

Criteria	JW 1/16/13	Yes	No
Primary Malignancy History			

Source: NCI Genomic Data Commons file f7c38adb-5ec7-47f6-b594-73cc09745c2c (TCGA-OR-A5KY.23328F06-11F8-4D12-BA95-D5CC9AEFE22A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).